Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABXO, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABXO-TTM1-A (Metastatic).

[page 1 of 6]
Results History

SURGICAL PATHOLOGY (Order

Result Date -

Component Results

Component

Report, pathology

Provider:

Collected:

Case #:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

COLON AT SPLENIC FLEXURE, BIOPSIES: MODERATELY DIFFERENTIATED

ADENOCARCINOMA

** Report Electronically Signed by **

Comment

Diagnosis called to

This specimen was diagnosed and signed out at the:

Clinical History

DIAGNOSIS / CLINICAL IMPRESSION:

Obstructing (by colonoscopy) mass at splenic flex, difficult to bx.

Gross Description

Received in formalin labeled are multiple tan-pink tissue fragments ranging from 0.1 cm to 0.3 cm in greatest dimension. Filtered; wrapped and entirely submitted in (A1).

Specimen(s) Received

A: COLON BIOPSY - splenic flex

Patient Name:

Med. Rec #:

DOB/Age:

Age: 66)

Sex: F

Facility:

Location: MEDICINE

Result Date

[page 2 of 6]
Transcription Result

Type Procedures	ID	Date and Time	Author

Procedure Orders:

1. CT ABDOMEN, W CONTRAST [REDACTED] ordered by at [REDACTED]
2. CT PELVIS, W CONTRAST [REDACTED] ordered by [REDACTED]

Document Text

CT ABDOMEN AND PELVIS

** HISTORY **:

65-year-old lady with atypical mid abdominal pain.

** FINDINGS **:

Thin section axial images of the abdomen and pelvis were performed following 80 mL of IV Visipaque 320 and oral contrast.

No prior studies for comparison.

There is an abnormal left upper quadrant mass which is inseparable from the splenic flexure of the colon. This heterogeneous density multilobulated lesion measures approximately 7.8 x 5.6 cm and does not result in colonic obstruction. Main differential considerations would include colonic adenocarcinoma or other GI neoplasm. There are a couple of small nodes adjacent to this lesion, none definitely enlarged by CT size criteria. The remainder of the bowel is unremarkable, with numerous sigmoid diverticuli incidentally noted.

Lung bases are clear. No pleural effusions. There is a 2.7 x 2.1 cm hypodense lesion of the posterior right hepatic lobe, which shows some peripheral nodular enhancement. A smaller 1 cm hypodense lesion of the left hepatic lobe is nonspecific. Metastases are not excluded given the left upper quadrant lesion. The spleen, pancreas, adrenal glands and kidneys are within normal limits. Pelvic structures are unremarkable. A small amount of nonspecific free pelvic fluid is noted.

No destructive osseous lesions are identified. There are some degenerative changes of the lower lumbar spine.

** IMPRESSION **:

1. Multilobulated left upper quadrant mass related to the splenic flexure of the colon. This is highly suspicious for neoplasm.
2. There are two hypodense liver lesions. The larger in the right hepatic lobe may represent a cavernous hemangioma, although there is a smaller nonspecific lesion of the left hepatic lobe. Metastasis is not excluded given the left upper quadrant abnormality.

These findings and impressions were discussed with the referring provider, [REDACTED] in a telephone conversation, at [REDACTED] hours on [REDACTED]. Action required dictation.

[REDACTED]

[REDACTED]

[page 4 of 6]
Transcription Result

Type	ID	Date	Author
Procedures	[REDACTED]	[REDACTED]	[REDACTED]

Procedure Orders:

1. PET W CONCURRENT CT, TUMOR LOCALIZATION, SKULL BASE TO MID THIGH [REDACTED] ordered by [REDACTED]
Radstatus, Inbound at [REDACTED]

Document Text

PET/CT BASE OF SKULL TO MID THIGH

** HISTORY **:

66 year-old woman with splenic flexure carcinoma of the colon with a possible metastases to the umbilicus.

** FINDINGS **:

TECHNIQUE: Radiopharmaceutical, 15 mCi F-18 deoxy glucose.
Fasting blood glucose: 94 mg per deciliter.

Approximately 50 minutes following the intravenous administration of the radiopharmaceutical, the patient was placed into the scanner. 6 bed positions with 4 minute emission images were obtained from the base of the skull to mid thighs. Images were reviewed in the sagittal, coronal, and axial planes. Please note that IV contrast was not given for the CT portion of the exam, and the CT should be considered not fully diagnostic and is used mainly for attenuation and localization purposes.

FINDINGS: A complex hypermetabolic mass with an SUV max of 18 .1 is noted at the splenic flexure the colon and represents this patient's primary lesion. 4 hypermetabolic masses are noted in the right lobe of the liver 2 in the dome and one on the medial aspect last in the inferior aspect of the right lobe. Another lesion is noted at the inferior aspect of the left lobe of the liver. Two hypermetabolic lymph nodes are noted in the area of the umbilicus with an SUV max of 11.4. Bilateral inguinal adenopathy is noted with the right more prominent than left. In the left lingula there is a hypermetabolic mass measuring approximately 2 cm with an SUV max of 8.6 also representing metastatic disease. Remainder the study is unremarkable with physiological tracer uptake by the base of the brain, heart, and a visualized urinary excretory system.

** IMPRESSION **:

Abnormal PET/CT scan to document this patient's known left splenic flexure malignancy. In addition metastatic disease is noted to the left hilum, at least 5 sites in the liver, lymph nodes in the umbilicus, and in both inguinal canals.

[REDACTED]

[REDACTED]

[page 5 of 6]
Transcription Result

Type	ID	Date	Author
Procedures	[REDACTED]	[REDACTED]	[REDACTED]

Procedure Orders:

1. PET W CONCURRENT CT TUMOR LOCALIZATION, SKULL BASE TO MID THIGH
Radstatus, Inbound at [REDACTED] ordered by [REDACTED]

Document Text

PET/CT BASE OF SKULL TO MID THIGH

** HISTORY **:

Cancer of the colon with metastases to liver, intra abdominal and intrathoracic lymph nodes and umbilicus.

** FINDINGS **:

Comparison: [REDACTED]

TECHNIQUE: Radiopharmaceutical, 15.5 mCi F-18 deoxy glucose.
Fasting blood glucose: 85 mg per deciliter.

Approximately 50 minutes following the intravenous administration of the radiopharmaceutical, the patient was placed into the scanner. 6 bed positions with 4 minute emission images were obtained from the base of the skull to mid thighs. Images were reviewed in the sagittal, coronal, and axial planes. Please note that the CT should be considered not fully diagnostic and is used mainly for attenuation and localization purposes.

FINDINGS:

Head and neck:

Physiologic uptake by the base of the brain. Sinuses are clear. No hypermetabolic lymph nodes noted.

Chest :

Venous access port noted in the right anterior chest. The previously noted left hilar lymph node has no detectable tracer uptake. Lung fields are clear. No lymphadenopathy present.

Abdomen and pelvis:

The lesion of the umbilicus is not detectable. No abnormalities are noted in the lymphatics of the mesentery or perivascular. No evidence of recurrence of the splenic flexure lesion. Physiologic uptake is noted in the liver without any discrete lesions. Spleen, bowel, adrenals all have physiologic uptake. Genitourinary system is normal.

MSK:

No lytic or blastic lesions noted.

** IMPRESSION **:

[REDACTED]

[page 6 of 6]
No significant abnormalities are noted in comparison to the prior study from [REDACTED]. This patient's appears to be experiencing a significant remission of of her metastatic colon cancer to her chemotherapeutic regimen. There is no evidence of active disease.

[REDACTED]

[REDACTED]

DD:

DT: [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f729f412-3d02-4d17-b23f-f18f5ce3797b (ER0192 ER-ABXO Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).